CPTAC case C3L-03356 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ef491908-1f1a-4428-9441-8dcd6e1b95b3

Demographics
Sex at birth: male; Race: white; Year of birth: 1946; Vital status: Alive; Country of birth: United Kingdom.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 71.5 years (26,098 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 550 days (1.5 years); Progression or recurrence: yes; Days to recurrence: 497 days (1.4 years); Days to last follow up: 550 days (1.5 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 11; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 497 days (1.4 years); Disease response: Progressive Disease; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 550 days (1.5 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 497 days (1.4 years); Karnofsky performance status: 80; ECOG performance status: 1.

Other clinical attributes
- Weight: 82 kg; Height: 169 cm; BMI: 28.71; Diabetes treatment type: Insulin.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03356-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 190.1 mg; Time between excision and freezing: 36 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03356-27: Section location: Head; Percent tumor nuclei: 40; Percent necrosis: 0.
- Sample C3L-03356-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
